Gene-level copy-number profile of tumor specimen TCGA-L5-A8NH-01A from TCGA case TCGA-L5-A8NH, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage IV; Tumor grade: GX; Age at diagnosis: 54.7 years (19,991 days).
Specimen TCGA-L5-A8NH-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ESCA.62824466-7d1d-4fd5-a02b-e1a5d4f86f85.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-L5-A8NH-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 813 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/8a36f70b-342b-4a49-adbc-993a2fc7eb45

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 3; copy number 2: 5,432; copy number 3: 27,806; copy number 4: 18,006; copy number 5: 4,033; copy number 6: 2,403; copy number 7: 1,241; copy number 8: 160; copy number 9: 127; copy number 10: 164; copy number 11: 28; copy number 12: 65; copy number 17: 86; copy number 18: 14; copy number 19: 97; copy number 22: 16; copy number 25: 62; copy number 26: 47; copy number 27: 20.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-L5-A8NH-01A-11D-A37B-01): tumor purity 0.72, ploidy 1.97, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:60,616,822–60,618,079, 2 genes: AC104164.2, MIR548BB.
- chr4:90,838,903–90,839,037, 1 gene: TMSB4XP8.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,127 genes in 16 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:30,248,350–45,895,970, 259 genes, copy number 7–9 (broad region; genes not listed).
- chr6:41,026,895–47,042,350, 178 genes, copy number 8–10 (broad region; genes not listed).
- chr7:55,019,017–55,433,742, 7 genes, copy number 11 (within-gene range 4–11): EGFR, EGFR-AS1, ELDR, AC073324.1, CALM1P2, AC073347.1, LANCL2.
- chr7:80,972,516–98,629,869, 226 genes, copy number 7–26 (broad region; genes not listed).
- chr8:150,584–4,994,972, 63 genes, copy number 8–12 (within-gene range 6–12) (broad region; genes not listed).
- chr8:5,127,919–5,911,236, 12 genes, copy number 9: AC019176.2, SNORA70, RN7SL318P, AC007718.1, AC091193.1, RPL23AP54, AC004944.1, AC084768.1, AC084768.2, AC087369.1, AC087369.2, RN7SKP159.
- chr8:9,899,871–12,388,296, 97 genes, copy number 19 (within-gene range 4–19) (broad region; genes not listed).
- chr8:49,817,586–51,015,165, 8 genes, copy number 10: AC113145.1, AC023762.1, SNTG1, AC090539.1, AC090539.2, CYCSP22, AC087272.1, AC090919.1.
- chr8:52,110,839–54,152,882, 34 genes, copy number 10: ST18, AC021915.2, AC021915.1, AC103831.1, RPL34P17, ALKAL1, RB1CC1, AC113139.1, NPBWR1, AC009800.1, AC009646.1, AC009646.2, OPRK1, AC131902.1, AC022034.3, AC131902.2, AC022034.1, AC022034.4, AC022034.2, MAPK6P1, AC103778.1, ATP6V1H, RGS20, AC113194.1, RPS27AP13, RNU6-1331P, TCEA1, AC100821.1, AC100821.2, LYPLA1, TDGF1P5, Metazoa_SRP, MRPL15, RNU6ATAC32P.
- chr8:57,594,166–60,136,599, 31 genes, copy number 8 (within-gene range 3–8): AC104051.1, AC104051.2, LINC01602, AC012103.1, FAM110B, AC104350.1, AC027698.1, RPL26P26, AC092819.3, AC092819.1, AC092819.2, UBXN2B, AC009927.1, CYP7A1, PPIAP85, SDCBP, NSMAF, AC068522.1, TOX, RNU4-50P, AC105150.1, AC090152.1, AC087698.1, RNA5SP267, AC087664.3, AC087664.1, AC087664.2, AC107934.1, AC107934.2, AC022709.1, AC021393.1.
- chr8:64,798,804–70,403,808, 87 genes, copy number 7 (within-gene range 3–7) (broad region; genes not listed).
- chr8:127,253,213–128,564,679, 23 genes, copy number 25 (within-gene range 3–25): AC018714.2, CASC8, AC018714.1, POU5F1B, CCAT2, AC104370.1, AC108925.1, CASC11, MYC, PVT1, MIR1204, AC084123.1, TMEM75, MIR1205, RNVU1-32, MIR1206, AC103705.1, RNU4-25P, MIR1207, MIR1208, RN7SKP226, AC100822.1, LINC00824.
- chr8:133,191,039–143,832,861, 182 genes, copy number 9–27 (broad region; genes not listed).
- chr11:72,002,864–72,290,688, 21 genes, copy number 7 (within-gene range 4–7): NUMA1, AP002490.1, RNU6-72P, MIR3165, AP000812.4, LRTOMT, LAMTOR1, AP000812.3, ANAPC15, FOLR3, RPEP6, FOLR1P1, AP000812.1, AP000812.2, FOLR1, FOLR2, INPPL1, PHOX2A, AP000593.2, AP000593.4, AP000593.1.
- chr11:72,302,139–72,302,965, 1 gene, copy number 7: AP000593.3.
- chr20:30,278,906–64,313,132, 898 genes, copy number 7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
